Somatic mutation profile of tumor specimen ALCH-AEUB-TTP1-A (aliquot ALCH-AEUB-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AEUB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 76.2 years (27,825 days).
Specimen ALCH-AEUB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bf4e88a-e243-4d30-ae28-5c44cab0c097.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEUB-NB1-A (Blood Derived Normal), aliquot ALCH-AEUB-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1a739d8-3d68-4c55-87da-3c523dadbab9

The open-access MAF lists 122 somatic variants for this specimen: 93 protein-altering or splice-affecting, 20 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 20, Nonsense Mutation 7, Intron 4, 3'UTR 4, Frame Shift Del 3, Splice Site 3, Splice Region 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1392_1403del p.D464_Y467del (on ENST00000521381 / NM_181523.3; = p.D194_Y197del on NM_181504.4) | In Frame Del (DEL) | VAF 59/532 reads (11%) | hotspot (GDC flag); called by mutect2, pindel
- TP53 | c.595G>T p.G199* | Nonsense Mutation (SNP) | VAF 40/231 reads (17%) | catalogued as rs1567551821, COSV52710769, COSV52715098, COSV52760685; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARNT | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs948601239; called by muse, mutect2, varscan2
- ATR | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 43/386 reads (11%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs535140939; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCL3 | c.1213C>A p.Q405K | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV99378289; called by muse, mutect2
- CDH18 | c.917C>G p.S306C | Missense Mutation (SNP) | VAF 105/301 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV56920085; called by muse, mutect2, varscan2
- CEP72 | c.126G>T p.K42N | Missense Mutation (SNP) | VAF 21/315 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99374388; called by muse, mutect2
- DNAH6 | c.10889G>A p.R3630Q | Missense Mutation (SNP) | VAF 60/433 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1473299954, COSV52870372; called by muse, mutect2, varscan2
- FANCI | c.1257T>G p.C419W | Missense Mutation (SNP) | VAF 82/499 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as rs1199204280; called by muse, mutect2, varscan2
- GOLGA6L2 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.316); catalogued as COSV61478604; called by muse, mutect2
- ITFG1 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs747170277, COSV57746508; called by muse, mutect2, varscan2
- KIT | c.1914G>T p.M638I | Missense Mutation (SNP) | VAF 82/486 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99855305; called by muse, mutect2, varscan2
- LRRTM4 | c.1048G>T p.V350F | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV69139301; called by muse, mutect2, varscan2
- MGA | c.3846A>G p.E1282= | Splice Region (SNP) | VAF 38/444 reads (9%) | catalogued as rs756777238; called by muse, mutect2
- MKX | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1255540276, COSV65391785; called by muse, mutect2, varscan2
- NABP2 | c.412A>G p.T138A | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV99907359; called by muse, mutect2, varscan2
- OR5T2 | c.533G>C p.R178T | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as rs879438417, COSV100507113; called by muse, mutect2, varscan2
- PIKFYVE | c.1219A>G p.I407V | Missense Mutation (SNP) | VAF 40/484 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs758679199; called by muse, mutect2
- SI | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 116/604 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs1476038133; called by muse, mutect2, varscan2
- SLC4A10 | c.2269C>T p.R757* (on ENST00000446997 / NM_001354461.2; = p.R727* on NM_022058.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 21/214 reads (10%) | catalogued as COSV55766747; called by muse, mutect2, varscan2
- SPTA1 | c.5222A>G p.Y1741C | Missense Mutation (SNP) | VAF 100/417 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.28); catalogued as rs774141948, COSV63760013; called by muse, mutect2, varscan2
- STPG2 | c.388-1G>C p.X130_splice | Splice Site (SNP) | VAF 25/111 reads (23%) | catalogued as COSV54796150; called by muse, mutect2, varscan2
- TEX2 | c.837A>T p.K279N | Missense Mutation (SNP) | VAF 51/390 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555632025; called by muse, mutect2, varscan2
- ZC2HC1A | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV55671489; called by muse, mutect2, varscan2
- ZNF628 | c.281G>A p.C94Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52699643; called by muse, mutect2, varscan2
- A1CF | c.1249A>T p.K417* (on ENST00000373993 / NM_138932.2; = p.K409* on NM_014576.4) | Nonsense Mutation (SNP) | VAF 48/309 reads (16%) | called by muse, mutect2, varscan2
- ACTN2 | c.743A>T p.Y248F | Missense Mutation (SNP) | VAF 136/363 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ADGRB3 | c.3035A>T p.Y1012F | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AP1G2 | c.1338T>G p.I446M | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- APBB1IP | c.39C>G p.S13R | Missense Mutation (SNP) | VAF 26/331 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARHGAP40 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.229); called by muse, varscan2
- ARHGEF4 | c.1700del p.V567Gfs*62 | Frame Shift Del (DEL) | VAF 9/79 reads (11%) | called by mutect2, pindel, varscan2
- CAPNS1 | c.199A>T p.S67C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- CCNL2 | c.1019A>G p.K340R | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- CDH20 | c.1596C>A p.S532R | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.734); called by muse, mutect2
- CGNL1 | c.2584G>T p.A862S | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- CLUH | c.2490+6A>T | Splice Region (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- DEFB110 | c.97A>G p.R33G | Missense Mutation (SNP) | VAF 47/359 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DLL4 | c.1391G>A p.C464Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAAF4 | c.966G>C p.K322N | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DST | c.21994C>T p.P7332S (on ENST00000361203 / NM_001374722.1; = p.P5005S on NM_015548.5) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, varscan2
- EBF3 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by mutect2, varscan2
- EML3 | c.1003C>G p.L335V | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ESPL1 | c.4790A>G p.Y1597C | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- F13A1 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FGA | c.2121C>G p.F707L | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- FOXA2 | c.1237G>T p.G413C (on ENST00000377115 / NM_153675.3; = p.G419C on NM_021784.5) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GPR15 | c.611T>C p.F204S | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIN3A | c.746A>C p.D249A | Missense Mutation (SNP) | VAF 11/235 reads (5%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2
- HCN1 | c.2185C>G p.L729V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- HNRNPDL | c.1207T>A p.Y403N | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KRBOX1 | c.44T>C p.V15A | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- L3MBTL3 | c.1025G>A p.W342* | Nonsense Mutation (SNP) | VAF 56/370 reads (15%) | called by muse, varscan2
- LBR | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 151/553 reads (27%) | called by muse, mutect2, varscan2
- LRP2 | c.10895G>T p.S3632I | Missense Mutation (SNP) | VAF 22/331 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.235); called by muse, mutect2
- MAF1 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- MUC17 | c.3506C>A p.T1169N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC4 | c.10082T>G p.L3361R | Missense Mutation (SNP) | VAF 36/643 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.774); called by muse, mutect2
- NPHS1 | c.840+2T>A p.X280_splice | Splice Site (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2, varscan2
- NR1H4 | c.1238A>C p.K413T (on ENST00000551379 / NM_001206993.2; = p.K399T on NM_005123.4) | Missense Mutation (SNP) | VAF 39/396 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); called by muse, mutect2
- NUP210 | c.4898A>T p.Q1633L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OBSL1 | c.5540A>T p.E1847V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.505); called by muse, varscan2
- OR10J5 | c.707C>A p.T236N | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- OR2M5 | c.344T>A p.L115* | Nonsense Mutation (SNP) | VAF 93/316 reads (29%) | called by muse, mutect2, varscan2
- OR9G4 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, varscan2
- PLCE1 | c.5605G>C p.A1869P | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PLEKHG2 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- PLXNA1 | c.2164G>T p.V722L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAB19 | c.140A>G p.Q47R | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- RALYL | c.37A>T p.K13* | Nonsense Mutation (SNP) | VAF 41/296 reads (14%) | called by muse, mutect2, varscan2
- RFWD3 | c.716del p.L239* | Frame Shift Del (DEL) | VAF 17/103 reads (17%) | called by mutect2, pindel, varscan2
- RFX6 | c.976C>G p.L326V | Missense Mutation (SNP) | VAF 35/313 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SEC24B | c.2881G>A p.A961T | Missense Mutation (SNP) | VAF 57/363 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- SLC12A3 | c.2140G>A p.A714T | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- SLC25A48 | c.585del p.F196Sfs*7 (on ENST00000650267; = p.F142Sfs*7 on NM_001349335.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/81 reads (12%) | called by mutect2, pindel, varscan2
- SLC35G4 | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- SLK | c.2481-2A>G p.X827_splice | Splice Site (SNP) | VAF 23/148 reads (16%) | called by muse, varscan2
- SMAD5 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SNX16 | c.436A>T p.T146S | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SPRED2 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SPTA1 | c.1051A>G p.S351G | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- SULT2A1 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 39/295 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- SVEP1 | c.1472C>A p.P491H | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TNFRSF10A | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by muse, varscan2
- TRAV21 | c.111C>G p.N37K | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- TRPV4 | c.1663A>T p.I555F | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- VEGFC | c.633C>G p.C211W | Missense Mutation (SNP) | VAF 56/365 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VSTM4 | c.222G>C p.L74F | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); called by muse, mutect2
- ZNF160 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ZNF431 | c.794G>A p.C265Y | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZNF713 | c.709C>G p.L237V (on ENST00000633730 / NM_001366796.2; = p.L250V on NM_182633.3) | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ZNF728 | c.197A>G p.K66R | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF845 | c.33G>C p.R11S | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- ADAMTSL1 | c.4218G>A p.L1406= | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as rs781227023; called by muse, mutect2, varscan2
- ASXL2 | c.3522C>T p.S1174= | Silent (SNP) | VAF 49/296 reads (17%) | called by muse, mutect2, varscan2
- ATP1A2 | c.1140C>A p.T380= | Silent (SNP) | VAF 22/191 reads (12%) | called by muse, mutect2, varscan2
- CDKN2A | c.291G>A p.L97= | Silent (SNP) | VAF 9/61 reads (15%) | called by muse, varscan2
- FN1 | c.6114C>T p.G2038= | Silent (SNP) | VAF 29/273 reads (11%) | called by muse, mutect2, varscan2
- GZMK | c.252A>G p.A84= | Silent (SNP) | VAF 47/238 reads (20%) | catalogued as COSV50249109; called by muse, mutect2, varscan2
- H3C2 | c.336C>A p.A112= | Silent (SNP) | VAF 21/148 reads (14%) | called by muse, mutect2, varscan2
- KIAA1109 | c.13641C>T p.F4547= | Silent (SNP) | VAF 37/152 reads (24%) | catalogued as rs374346916; called by muse, mutect2, varscan2
- KIF3C | c.1263C>T p.Y421= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- NR1H2 | c.885C>G p.G295= | Silent (SNP) | VAF 6/33 reads (18%) | called by muse, varscan2
- OR56B4 | c.477C>T p.G159= | Silent (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- PCDH10 | c.2694T>G p.S898= | Silent (SNP) | VAF 20/140 reads (14%) | called by muse, mutect2
- PJVK | c.846C>T p.L282= | Silent (SNP) | VAF 30/348 reads (9%) | called by muse, mutect2
- PPIL3 | c.303C>T p.F101= (on ENST00000392283 / NM_130906.3; = p.F105= on NM_032472.4) | Silent (SNP) | VAF 48/335 reads (14%) | called by muse, mutect2, varscan2
- PRODH2 | c.1560C>T p.S520= (on ENST00000301175; = p.S444= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs1247507683; called by muse, varscan2
- PRPF8 | c.3018C>T p.A1006= | Silent (SNP) | VAF 29/189 reads (15%) | catalogued as rs192274713; called by muse, mutect2, varscan2
- SCFD1 | c.210C>A p.I70= | Silent (SNP) | VAF 57/374 reads (15%) | called by muse, mutect2, varscan2
- SLC20A1 | c.1140C>T p.T380= | Silent (SNP) | VAF 30/167 reads (18%) | catalogued as rs376731717; called by muse, mutect2, varscan2
- SLC4A1AP | c.159G>A p.L53= | Silent (SNP) | VAF 54/257 reads (21%) | called by muse, mutect2, varscan2
- ZNF714 | c.459A>G p.S153= | Silent (SNP) | VAF 50/206 reads (24%) | catalogued as rs1304016303; called by muse, mutect2, varscan2
- GABRB3 | c.241-7522C>T | Intron (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- LYRM9 | c.*24G>T | 3'UTR (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- NLGN4Y | c.*1136G>T | 3'UTR (SNP) | VAF 89/272 reads (33%) | called by muse, mutect2, varscan2
- PDCD10 | c.151-848A>T | Intron (SNP) | VAF 60/482 reads (12%) | called by muse, mutect2, varscan2
- RHBDD1 | c.857-7092A>T | Intron (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- RPS26P15 | n.52G>A | RNA (SNP) | VAF 19/144 reads (13%) | catalogued as rs746411167; called by muse, mutect2, varscan2
- TBX22 | c.*10A>T | 3'UTR (SNP) | VAF 35/102 reads (34%) | called by muse, mutect2, varscan2
- TPH2 | c.609-10941G>T | Intron (SNP) | VAF 32/205 reads (16%) | called by muse, mutect2, varscan2
- UNC5D | c.*2639G>T | 3'UTR (SNP) | VAF 154/310 reads (50%) | called by muse, mutect2, varscan2
